Somatic mutation profile of tumor specimen MP2PRT-PAVYHF-TMP1-B (aliquot MP2PRT-PAVYHF-TMP1-B-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVYHF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,782 days).
Specimen MP2PRT-PAVYHF-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66a4e4cf-63ea-47b2-9dbf-28c7c2c14229.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYHF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYHF-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ba02ce7-af2e-4324-87de-fa97e5e1e2d3

The open-access MAF lists 47 somatic variants for this specimen: 32 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, In Frame Ins 2, Nonsense Mutation 2, Intron 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 92/341 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749983338, COSV104418828; called by muse, mutect2, varscan2
- AP1G2 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 70/261 reads (27%) | catalogued as rs138038447; called by muse, mutect2, varscan2
- ARAP3 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 103/501 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.16); catalogued as rs1444117400; called by muse, mutect2, varscan2
- CAVIN4 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 130/249 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs191289133, COSV56867210; called by muse, mutect2, varscan2
- CDRT15L2 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 166/493 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs781289190, COSV101207250; called by muse, mutect2, varscan2
- CPA4 | c.1159G>T p.G387W | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55982711; called by muse, mutect2, varscan2
- CYP2C9 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs17847037; called by muse, mutect2
- EP300 | c.3631G>T p.E1211* | Nonsense Mutation (SNP) | VAF 10/287 reads (3%) | catalogued as COSV54330588; called by muse, mutect2
- FLNC | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 197/416 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs766439553, COSV57952051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRID2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 30/639 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as rs780468524, COSV99937918; called by muse, mutect2
- IZUMO3 | c.492C>T p.D164= (on ENST00000543880 / NM_001365008.2; = p.D158= on NM_001271706.1) | Splice Region (SNP) | VAF 89/196 reads (45%) | catalogued as rs570228543, COSV101371505; called by muse, varscan2
- KCNQ1 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 154/332 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs764236591, COSV50137507; called by muse, mutect2, varscan2
- KLK3 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 145/285 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs866995758; called by muse, mutect2, varscan2
- OR51I2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs144988492, COSV58298151; called by muse, mutect2
- PARP14 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs745695997; called by muse, mutect2, varscan2
- RADIL | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs779249892, COSV68199670; called by muse, mutect2, varscan2
- RIT1 | c.246delinsGCCC p.F82delinsLP | In Frame Ins (INS) | VAF 104/304 reads (34%) | catalogued as CM136416, COSV64170802, COSV64171107; called by mutect2*, pindel, varscan2*
- SEMA5A | c.2746C>T p.R916C | Missense Mutation (SNP) | VAF 107/502 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913733262; called by muse, mutect2, varscan2
- SERPINA2 | c.364T>A p.C122S | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.946); catalogued as rs1349067562; called by muse, mutect2
- YTHDC2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV50748251; called by muse, mutect2, varscan2
- AKR1B15 | c.526_527insGCG p.L176delinsRV | In Frame Ins (INS) | VAF 74/202 reads (37%) | called by mutect2, pindel, varscan2
- C4orf46 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 150/775 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CALHM4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 123/272 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CTTNBP2 | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- DHX16 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 206/652 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- ECHDC2 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 161/316 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GCC2 | c.4751C>G p.A1584G | Missense Mutation (SNP) | VAF 93/410 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL4 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- KNDC1 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 210/700 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT14 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SEMA6B | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TLN1 | c.7189G>T p.A2397S | Missense Mutation (SNP) | VAF 97/111 reads (87%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ADNP2 | c.310C>T p.L104= | Silent (SNP) | VAF 18/440 reads (4%) | called by muse, mutect2
- AHDC1 | c.2832C>T p.F944= | Silent (SNP) | VAF 266/521 reads (51%) | called by muse, mutect2, varscan2
- ANK3 | c.9786G>A p.A3262= | Silent (SNP) | VAF 113/378 reads (30%) | catalogued as rs149717308; called by muse, varscan2
- C8orf34 | c.219C>T p.R73= | Silent (SNP) | VAF 30/484 reads (6%) | called by muse, mutect2
- CHI3L2 | c.138C>T p.F46= | Silent (SNP) | VAF 169/357 reads (47%) | called by muse, mutect2, varscan2
- COL18A1 | c.372C>T p.F124= | Silent (SNP) | VAF 239/900 reads (27%) | catalogued as rs372080967; called by muse, mutect2, varscan2
- FAT4 | c.10389G>A p.Q3463= | Silent (SNP) | VAF 156/456 reads (34%) | called by muse, mutect2, varscan2
- LIMK1 | c.1935C>A p.V645= | Silent (SNP) | VAF 95/340 reads (28%) | called by muse, mutect2, varscan2
- MYH10 | c.5283G>A p.K1761= | Silent (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- MYO1C | c.2625C>T p.A875= (on ENST00000648651 / NM_001080779.2; = p.A840= on NM_033375.5) | Silent (SNP) | VAF 106/377 reads (28%) | catalogued as rs374091489, COSV100704179; called by muse, mutect2, varscan2
- OSBPL10 | c.288C>T p.F96= | Silent (SNP) | VAF 98/224 reads (44%) | catalogued as rs549731324, COSV67343817; called by muse, mutect2, varscan2
- PEG3 | c.423C>T p.D141= | Silent (SNP) | VAF 24/343 reads (7%) | catalogued as rs755423178, COSV55631363; called by muse, mutect2
- SRRM2 | c.2286C>T p.L762= | Silent (SNP) | VAF 201/389 reads (52%) | catalogued as rs758899562, COSV57069142; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins GGTGCCTCGG | 3'Flank (INS) | VAF 62/230 reads (27%) | called by mutect2, pindel*, varscan2
- PRRX1 | c.599+3882G>A | Intron (SNP) | VAF 189/339 reads (56%) | catalogued as rs375494824; called by muse, mutect2, varscan2
